Gene-level copy-number profile of tumor specimen TCGA-69-7973-01A from TCGA case TCGA-69-7973, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 42.0 years (15,355 days).
Specimen TCGA-69-7973-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.70feb869-bf25-4614-9e66-8e0c89aac7e1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-69-7973-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4226ec3e-0711-407f-97f5-879a73de976c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 318; copy number 2: 13,755; copy number 3: 17,372; copy number 4: 20,011; copy number 5: 5,048; copy number 6: 3,311.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-69-7973-01A-11D-2183-01): tumor purity 0.55, ploidy 3.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 318. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
